Somatic mutation profile of tumor specimen MMRF_2774_1_BM_CD138pos (aliquot MMRF_2774_1_BM_CD138pos_T1_KHS5U_L15723) from MMRF case MMRF_2774, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow.
Specimen MMRF_2774_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 11779395-e6f1-446b-99a5-c3830e779192.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2774_1_PB_WBC (Blood Derived Normal), aliquot MMRF_2774_1_PB_WBC_C3_KHS5U_L15767; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f7c2bc57-dcb6-46a6-9c69-0c041e94a122

The open-access MAF lists 138 somatic variants for this specimen: 40 protein-altering or splice-affecting, 14 silent, 84 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 3'UTR 48, Missense Mutation 34, Intron 17, Silent 14, 5'UTR 9, RNA 4, 5'Flank 3, 3'Flank 3, Splice Site 2, Nonsense Mutation 2, Splice Region 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATRNL1 | c.3373G>A p.D1125N | Missense Mutation (SNP) | VAF 59/146 reads (40%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.989); catalogued as COSV58089218; called by muse, mutect2, varscan2
- CFC1 | c.241G>T p.G81* | Nonsense Mutation (SNP) | VAF 29/156 reads (19%) | catalogued as COSV52090420; called by muse, mutect2, varscan2
- ECEL1 | c.472G>A p.E158K | Missense Mutation (SNP) | VAF 23/59 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.542); catalogued as rs752100039; called by muse, mutect2, varscan2
- EGR1 | c.245G>A p.S82N | Missense Mutation (SNP) | VAF 77/140 reads (55%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.001); catalogued as rs898320714; called by muse, mutect2, varscan2
- FAM83A | c.926C>T p.P309L | Missense Mutation (SNP) | VAF 89/199 reads (45%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as rs970806160, COSV52685481; called by muse, mutect2, varscan2
- FO681492.1 | c.646C>T p.R216W | Missense Mutation (SNP) | VAF 24/56 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1482720347; called by mutect2, varscan2
- GUK1 | c.551C>T p.A184V | Missense Mutation (SNP) | VAF 100/201 reads (50%) | SIFT tolerated (0.36); PolyPhen benign (0.001); catalogued as rs202143318; called by muse, mutect2, varscan2
- HKDC1 | c.2373C>T p.S791= | Splice Region (SNP) | VAF 61/155 reads (39%) | catalogued as rs754500258, COSV63579731; called by muse, mutect2, varscan2
- IGLV1-44 | c.42T>G p.C14W | Missense Mutation (SNP) | VAF 82/181 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.787); catalogued as rs1220956860; called by muse, varscan2
- IGLV7-46 | c.308A>C p.D103A | Missense Mutation (SNP) | VAF 50/118 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs749946995; called by muse, mutect2, varscan2
- KLHDC7A | c.550G>A p.E184K | Missense Mutation (SNP) | VAF 131/358 reads (37%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as rs750747962, COSV68770690; called by muse, mutect2, varscan2
- PATL2 | c.868C>A p.Q290K | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT tolerated (0.52); PolyPhen probably damaging (0.932); catalogued as COSV71384380; called by muse, mutect2, varscan2
- PIGZ | c.731G>A p.R244H | Missense Mutation (SNP) | VAF 26/314 reads (8%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs202144183, COSV53014050; called by muse, mutect2
- RELCH | c.3424C>T p.R1142W | Missense Mutation (SNP) | VAF 123/319 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); catalogued as rs139480966; called by muse, mutect2, varscan2
- REV3L | c.4911T>A p.D1637E | Missense Mutation (SNP) | VAF 9/156 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as rs1319804023; called by muse, mutect2
- SPAG17 | c.1888G>A p.E630K | Missense Mutation (SNP) | VAF 138/319 reads (43%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); catalogued as COSV60452433; called by muse, mutect2, varscan2
- VPS13A | c.2970T>A p.N990K | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.722); catalogued as rs774698356; called by mutect2, varscan2
- ANLN | c.373G>A p.G125S | Missense Mutation (SNP) | VAF 13/158 reads (8%) | SIFT tolerated (0.63); PolyPhen benign (0.007); called by muse, mutect2
- ARID4A | c.536T>A p.V179E | Missense Mutation (SNP) | VAF 13/181 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2
- BCL7A | c.92+2T>A p.X31_splice | Splice Site (SNP) | VAF 79/192 reads (41%) | called by muse, mutect2, varscan2
- CDK20 | c.454T>A p.F152I | Missense Mutation (SNP) | VAF 38/83 reads (46%) | SIFT tolerated (0.06); PolyPhen benign (0.291); called by muse, mutect2, varscan2
- CFAP54 | c.7619T>G p.L2540* | Nonsense Mutation (SNP) | VAF 44/131 reads (34%) | called by muse, mutect2, varscan2
- CNOT1 | c.71A>T p.N24I | Missense Mutation (SNP) | VAF 29/175 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.795); called by muse, mutect2, varscan2
- EFHC2 | c.1091A>T p.Y364F | Missense Mutation (SNP) | VAF 17/153 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.983); called by muse, varscan2
- EIF2D | c.1053-1G>C p.X351_splice | Splice Site (SNP) | VAF 8/164 reads (5%) | called by muse, mutect2
- GRM2 | c.2071C>A p.L691M | Missense Mutation (SNP) | VAF 12/304 reads (4%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.983); called by muse, mutect2
- IGLC3 | c.197A>T p.Y66F | Missense Mutation (SNP) | VAF 30/75 reads (40%) | PolyPhen possibly damaging (0.498); called by muse, mutect2
- IGLV5-45 | c.222C>G p.D74E | Missense Mutation (SNP) | VAF 61/144 reads (42%) | SIFT tolerated (0.1); PolyPhen benign (0.369); called by muse, mutect2, varscan2
- KIF14 | c.3322T>C p.Y1108H | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.898); called by muse, mutect2
- NR3C2 | c.1563G>T p.Q521H | Missense Mutation (SNP) | VAF 93/230 reads (40%) | SIFT tolerated (0.51); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- OR5M10 | c.697G>A p.G233S | Missense Mutation (SNP) | VAF 52/167 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PNMA5 | c.728C>T p.A243V | Missense Mutation (SNP) | VAF 51/121 reads (42%) | SIFT tolerated (0.42); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PTCHD4 | c.2516A>C p.N839T | Missense Mutation (SNP) | VAF 116/284 reads (41%) | SIFT tolerated (0.37); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- SYNM | c.2897A>T p.E966V | Missense Mutation (SNP) | VAF 7/133 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.249); called by muse, mutect2
- TMEM50B | c.99+6T>C | Splice Region (SNP) | VAF 92/435 reads (21%) | called by muse, mutect2, varscan2
- UTRN | c.8918G>A p.R2973K | Missense Mutation (SNP) | VAF 11/75 reads (15%) | SIFT tolerated (0.26); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- VPS13B | c.3641T>G p.L1214R | Missense Mutation (SNP) | VAF 46/109 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.548); called by muse, mutect2, varscan2
- ZNF431 | c.1014T>G p.H338Q | Missense Mutation (SNP) | VAF 60/159 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ZNF451 | c.1158C>A p.H386Q | Missense Mutation (SNP) | VAF 103/216 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); called by muse, mutect2, varscan2
- ZNF662 | c.235C>A p.P79T | Missense Mutation (SNP) | VAF 19/284 reads (7%) | SIFT tolerated (0.25); PolyPhen benign (0.354); called by muse, mutect2
- ACER1 | c.399T>A p.L133= | Silent (SNP) | VAF 67/134 reads (50%) | catalogued as COSV56835977; called by muse, mutect2, varscan2
- ADAM30 | c.936G>T p.V312= | Silent (SNP) | VAF 14/204 reads (7%) | called by muse, mutect2
- ASPSCR1 | c.1095C>T p.R365= | Silent (SNP) | VAF 63/127 reads (50%) | called by muse, mutect2, varscan2
- COL9A1 | c.423A>G p.Q141= | Silent (SNP) | VAF 152/357 reads (43%) | called by muse, mutect2, varscan2
- CXorf66 | c.1023T>A p.V341= | Silent (SNP) | VAF 17/164 reads (10%) | called by muse, mutect2
- DNAH5 | c.1779T>A p.L593= | Silent (SNP) | VAF 11/163 reads (7%) | called by muse, mutect2
- PCDHGA4 | c.1836C>T p.S612= | Silent (SNP) | VAF 21/207 reads (10%) | catalogued as rs374189449, COSV99533247; called by muse, mutect2, varscan2
- PTPN18 | c.795T>A p.L265= | Silent (SNP) | VAF 24/340 reads (7%) | called by muse, mutect2
- PUS1 | c.1227G>A p.T409= | Silent (SNP) | VAF 24/45 reads (53%) | catalogued as rs759432103; ClinVar: likely benign; called by muse, varscan2
- RAB3IL1 | c.981G>A p.S327= | Silent (SNP) | VAF 47/133 reads (35%) | catalogued as rs376882014, COSV57117378; called by muse, mutect2, varscan2
- SCN4A | c.4071C>A p.I1357= | Silent (SNP) | VAF 24/387 reads (6%) | called by muse, mutect2
- SKA3 | c.672T>G p.G224= | Silent (SNP) | VAF 7/104 reads (7%) | called by muse, mutect2
- TDRD3 | c.753G>A p.R251= | Silent (SNP) | VAF 8/143 reads (6%) | catalogued as rs773765043; called by muse, mutect2
- ZNF282 | c.1317G>T p.P439= | Silent (SNP) | VAF 20/45 reads (44%) | called by muse, mutect2, varscan2
- AC009779.3 | c.*253A>G | 3'UTR (SNP) | VAF 17/181 reads (9%) | catalogued as rs567868189; called by muse, mutect2
- AC073140.1 | n.65C>T | RNA (SNP) | VAF 19/41 reads (46%) | catalogued as rs756244663; called by muse, mutect2, varscan2
- AC244197.3 | c.*5398A>G | 3'UTR (SNP) | VAF 117/252 reads (46%) | called by muse, mutect2, varscan2
- ACOT12 | c.*317C>A | 3'UTR (SNP) | VAF 9/97 reads (9%) | called by muse, mutect2
- ADGRL2 | c.2132-55A>C | Intron (SNP) | VAF 21/46 reads (46%) | called by muse, mutect2, varscan2
- APOBEC3D | c.*107C>A | 3'UTR (SNP) | VAF 73/145 reads (50%) | called by muse, mutect2, varscan2
- APPL1 | c.-5C>G | 5'UTR (SNP) | VAF 37/56 reads (66%) | called by muse, mutect2, varscan2
- BIRC8 | n.1750T>G | RNA (SNP) | VAF 35/75 reads (47%) | called by muse, mutect2, varscan2
- C16orf70 | c.*1084A>T | 3'UTR (SNP) | VAF 11/94 reads (12%) | called by muse, mutect2, varscan2
- CALCR | c.*1692T>C | 3'UTR (SNP) | VAF 97/217 reads (45%) | catalogued as rs992482176; called by muse, mutect2, varscan2
- CCDC69 | c.*1160T>C | 3'UTR (SNP) | VAF 93/197 reads (47%) | called by muse, mutect2, varscan2
- CD37 | c.-17T>G | 5'UTR (SNP) | VAF 60/142 reads (42%) | called by muse, mutect2, varscan2
- CDH22 | c.*691G>A | 3'UTR (SNP) | VAF 68/167 reads (41%) | called by muse, mutect2, varscan2
- CFAP57 | c.1929+705A>T | Intron (SNP) | VAF 5/48 reads (10%) | called by muse, mutect2
- CHMP1B | c.-19C>A | 5'UTR (SNP) | VAF 91/228 reads (40%) | catalogued as rs1379975960; called by muse, mutect2, varscan2
- CLCN4 | c.*1226T>G | 3'UTR (SNP) | VAF 59/150 reads (39%) | called by muse, mutect2, varscan2
- CLDN4 | chr7:73830692 A>C | 5'Flank (SNP) | VAF 13/105 reads (12%) | called by muse, mutect2, varscan2
- CNOT2 | c.*63A>T | 3'UTR (SNP) | VAF 58/132 reads (44%) | called by muse, mutect2, varscan2
- COBL | c.1096+11822T>C | Intron (SNP) | VAF 23/180 reads (13%) | called by muse, mutect2, varscan2
- CSF3 | c.-29G>T | 5'UTR (SNP) | VAF 10/136 reads (7%) | called by muse, mutect2
- GANC | c.*303G>A | 3'UTR (SNP) | VAF 13/123 reads (11%) | catalogued as rs560991771; called by muse, mutect2, varscan2
- GNAO1 | c.464+39G>A | Intron (SNP) | VAF 10/85 reads (12%) | called by muse, mutect2, varscan2
- GRID2IP | chr7:6497609 C>T | 3'Flank (SNP) | VAF 14/46 reads (30%) | called by muse, mutect2, varscan2
- GUCY1A1 | c.*1762T>G | 3'UTR (SNP) | VAF 6/94 reads (6%) | catalogued as rs1384435373; called by muse, mutect2
- HCFC2 | c.*1486_*1489del | 3'UTR (DEL) | VAF 6/60 reads (10%) | catalogued as rs546114350; called by mutect2, pindel
- HMG20A | c.*6+16T>C | Intron (SNP) | VAF 128/313 reads (41%) | called by muse, mutect2, varscan2
- HOXC4 | chr12:54055596 G>C | 3'Flank (SNP) | VAF 42/105 reads (40%) | called by muse, mutect2, varscan2
- ICAM2 | c.61+139C>G | Intron (SNP) | VAF 39/90 reads (43%) | called by muse, mutect2, varscan2
- IGHV3-74 | c.-33T>C | 5'UTR (SNP) | VAF 87/164 reads (53%) | called by muse, mutect2, varscan2
- IL17RD | c.*760C>T | 3'UTR (SNP) | VAF 14/327 reads (4%) | called by muse, mutect2
- KCNC1 | c.*3375G>A | 3'UTR (SNP) | VAF 58/99 reads (59%) | catalogued as rs996815383; called by muse, mutect2, varscan2
- KLHL3 | c.*3436G>C | 3'UTR (SNP) | VAF 44/99 reads (44%) | called by muse, mutect2, varscan2
- LMTK2 | c.*686T>G | 3'UTR (SNP) | VAF 11/63 reads (17%) | catalogued as rs886677318; called by muse, mutect2, varscan2
- LRCOL1 | c.106-93A>T | Intron (SNP) | VAF 30/94 reads (32%) | called by muse, mutect2
- LRP12 | c.*407T>A | 3'UTR (SNP) | VAF 36/89 reads (40%) | called by muse, mutect2, varscan2
- LRRC55 | c.*3689C>T | 3'UTR (SNP) | VAF 12/152 reads (8%) | catalogued as rs1355295083; called by muse, mutect2
- MMP16 | c.*2109T>C | 3'UTR (SNP) | VAF 60/119 reads (50%) | called by muse, mutect2, varscan2
- MORC4 | c.*225T>A | 3'UTR (SNP) | VAF 36/84 reads (43%) | called by muse, mutect2, varscan2
- MPHOSPH9 | c.*393T>G | 3'UTR (SNP) | VAF 6/135 reads (4%) | called by muse, mutect2
- MTHFS | c.117+38A>G | Intron (SNP) | VAF 64/170 reads (38%) | called by muse, mutect2, varscan2
- MYH6 | c.1581+93C>T | Intron (SNP) | VAF 10/136 reads (7%) | called by muse, mutect2
- NUP50 | c.*2117C>T | 3'UTR (SNP) | VAF 37/85 reads (44%) | catalogued as rs537571847; called by muse, mutect2, varscan2
- OSTF1 | c.*327T>C | 3'UTR (SNP) | VAF 6/76 reads (8%) | catalogued as rs1195819009; called by muse, mutect2
- OTX1 | c.*882C>T | 3'UTR (SNP) | VAF 54/117 reads (46%) | called by muse, mutect2, varscan2
- PABPC1P2 | n.850A>C | RNA (SNP) | VAF 42/205 reads (20%) | called by muse, mutect2, varscan2
- PCDH19 | c.-628C>T | 5'UTR (SNP) | VAF 67/168 reads (40%) | called by muse, mutect2, varscan2
- PHB2 | c.-21C>T | 5'UTR (SNP) | VAF 4/45 reads (9%) | called by muse, mutect2
- PI4KAP2 | chr22:21492040 del C | 5'Flank (DEL) | VAF 6/61 reads (10%) | catalogued as rs66595525; called by pindel, varscan2
- PPME1 | c.*202C>T | 3'UTR (SNP) | VAF 142/287 reads (49%) | called by muse, mutect2, varscan2
- PRKAG2 | c.684+61A>C | Intron (SNP) | VAF 76/161 reads (47%) | called by muse, mutect2, varscan2
- PRLR | c.*7708G>A | 3'UTR (SNP) | VAF 9/83 reads (11%) | called by muse, mutect2, varscan2
- PRRG3 | c.*966A>C | 3'UTR (SNP) | VAF 48/121 reads (40%) | called by muse, mutect2, varscan2
- PTGFRN | c.*3048T>C | 3'UTR (SNP) | VAF 8/92 reads (9%) | called by muse, mutect2
- RABGGTB | c.*289T>G | 3'UTR (SNP) | VAF 28/95 reads (29%) | called by muse, mutect2, varscan2
- RCCD1 | c.-63T>G | 5'UTR (SNP) | VAF 6/90 reads (7%) | called by muse, mutect2
- RECK | c.*213G>A | 3'UTR (SNP) | VAF 23/54 reads (43%) | called by muse, mutect2, varscan2
- RNF150 | c.*1661C>T | 3'UTR (SNP) | VAF 39/77 reads (51%) | catalogued as rs1486840116; called by muse, mutect2
- ROBO1 | c.*790C>A | 3'UTR (SNP) | VAF 11/146 reads (8%) | called by muse, mutect2
- RPSAP52 | n.996T>C | RNA (SNP) | VAF 12/71 reads (17%) | called by muse, mutect2, varscan2
- RRP15 | c.*2944A>T | 3'UTR (SNP) | VAF 29/82 reads (35%) | called by muse, mutect2, varscan2
- RSPO4 | c.*1515G>C | 3'UTR (SNP) | VAF 15/223 reads (7%) | called by muse, mutect2
- SDK1 | c.*471G>C | 3'UTR (SNP) | VAF 111/224 reads (50%) | catalogued as rs779191335; called by muse, mutect2, varscan2
- SESN3 | c.*1905T>G | 3'UTR (SNP) | VAF 9/161 reads (6%) | called by muse, mutect2
- SLC41A3 | c.599-124A>T | Intron (SNP) | VAF 9/42 reads (21%) | called by muse, mutect2
- SOCS2 | c.-213-366C>T | Intron (SNP) | VAF 27/285 reads (9%) | called by muse, mutect2
- SOX11 | c.*2116A>T | 3'UTR (SNP) | VAF 51/109 reads (47%) | called by muse, mutect2, varscan2
- SP5 | chr2:170714051 G>A | 5'Flank (SNP) | VAF 7/55 reads (13%) | catalogued as rs1367990793; called by muse, mutect2, varscan2
- SPTSSB | c.-1020G>T | 5'UTR (SNP) | VAF 86/354 reads (24%) | catalogued as COSV63219313; called by muse, mutect2, varscan2
- SRGAP3 | c.*3094T>G | 3'UTR (SNP) | VAF 61/98 reads (62%) | called by muse, mutect2, varscan2
- SUV39H2 | c.849+597del | Intron (DEL) | VAF 17/46 reads (37%) | called by pindel, varscan2
- SUV39H2 | c.849+649T>G | Intron (SNP) | VAF 10/22 reads (45%) | catalogued as rs1336705324; called by muse, varscan2
- TENT5C | c.*2241T>A | 3'UTR (SNP) | VAF 40/154 reads (26%) | called by muse, mutect2, varscan2
- TMED5 | c.*375T>A | 3'UTR (SNP) | VAF 7/61 reads (11%) | called by muse, mutect2, varscan2
- TMED7-TICAM2 | c.*1634A>C | 3'UTR (SNP) | VAF 5/88 reads (6%) | called by muse, mutect2
- TMEM126B | c.*276A>G | 3'UTR (SNP) | VAF 17/43 reads (40%) | called by muse, mutect2, varscan2
- TMEM255A | c.*2217G>A | 3'UTR (SNP) | VAF 19/42 reads (45%) | catalogued as rs1220116139; called by muse, mutect2, varscan2
- TMEM41B | c.*54-66G>A | Intron (SNP) | VAF 5/66 reads (8%) | called by muse, mutect2
- TRIM11 | c.860-634T>C | Intron (SNP) | VAF 81/215 reads (38%) | called by muse, mutect2, varscan2
- TRIM8 | c.*1405C>T | 3'UTR (SNP) | VAF 36/102 reads (35%) | called by muse, mutect2, varscan2
- TSPAN5 | c.*1978G>T | 3'UTR (SNP) | VAF 7/95 reads (7%) | called by muse, mutect2
- WBP2 | c.60-55T>C | Intron (SNP) | VAF 40/99 reads (40%) | called by muse, mutect2, varscan2
- ZNF143 | c.*304T>A | 3'UTR (SNP) | VAF 30/61 reads (49%) | called by muse, mutect2, varscan2
- ZNF516 | c.*1528T>C | 3'UTR (SNP) | VAF 28/77 reads (36%) | called by muse, mutect2, varscan2
- ZNF625 | chr19:12142175 C>T | 3'Flank (SNP) | VAF 10/226 reads (4%) | called by muse, mutect2
